CCDI case PBBZBP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4685f8b2-50ca-434c-b7eb-76e17237a211

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.8 years (641 days).

Biospecimens (3 samples)
- Sample 0DLA11: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLA1Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DLA2V: Tissue type: Tumor; Specimen type: Solid Tissue.
